Surgical pathology report (de-identified scan), TCGA case TCGA-CW-5583, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-CW-5583-01A (Primary Tumor).

[page 1 of 2]
Surgical Pathology

TISSUE DESCRIPTION:

Tissue from the right kidney (No. 1--12.6 x 4.1 x 3.5 cm, No. 2--1.3 x 0.6 x 0.5 cm) and right posterior kidney (2 x 1.2 x 1.2 cm)

DIAGNOSIS:

Kidney, right, partial nephrectomy: Grade 2 (of 4) renal cell carcinoma, clear cell type, forming a 3.6 x 3 x 2.1 cm mass. The tumor is confined to the kidney. The tumor does not involve the collecting system. Coagulation tumor necrosis is absent. The surgical resection margins are microscopically focally positive.

Kidney, right, excision No. 2: Grade 2 (of 4) renal cell carcinoma, clear cell type, forming a 0.4 x 0.4 x 0.4 cm., completely excised.

Kidney, right posterior, excision: Invasive grade 2 (of 4) renal cell carcinoma, papillary cell type, forming a 1.5 x 1.2 x 1.1 cm., completely excised.

[page 2 of 2]
Surgical Pathology

TISSUE DESCRIPTION:

Tissue from the right kidney (No. 1--12.6 x 4.1 x 3.5 cm, No. 2--1.3 x 0.6 x 0.5 cm) and right posterior kidney (2 x 1.2 x 1.2 cm)

DIAGNOSIS:

Kidney, right, partial nephrectomy: Grade 2 (of 4) renal cell carcinoma, clear cell type, forming a 3.6 x 3 x 2.1 cm mass. The tumor is confined to the kidney. The tumor does not involve the collecting system. Coagulation tumor necrosis is absent. The surgical resection margins are microscopically focally positive.

Kidney, right, excision No. 2: Grade 2 (of 4) renal cell carcinoma, clear cell type, forming a 0.4 x 0.4 x 0.4 cm., completely excised.

Kidney, right posterior, excision: Invasive grade 2 (of 4) renal cell carcinoma, papillary cell type, forming a 1.5 x 1.2 x 1.1 cm., completely excised.

Source: NCI Genomic Data Commons file 4399c79d-829d-42f3-82e1-d7e97f0dea77 (TCGA-CW-5583.DB2008C5-DAFE-40AA-AC4B-66C33DBFA3A6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).